Somatic mutation profile of tumor specimen TCGA-25-1326-01A (aliquot TCGA-25-1326-01A-01W-0492-08) from TCGA case TCGA-25-1326, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.2 years (22,339 days).
Specimen TCGA-25-1326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca82229-81f1-419f-a1de-41ac2a20bc6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1326-10A (Blood Derived Normal), aliquot TCGA-25-1326-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4323f367-06b6-44bc-8a0b-8f5971ccfc64

The open-access MAF lists 211 somatic variants for this specimen: 163 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 42, Nonsense Mutation 9, Splice Site 6, Frame Shift Del 2, Splice Region 2, 5'Flank 2, RNA 2, In Frame Del 1, Frame Shift Ins 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 182/283 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZIC1 | c.1163C>A p.S388* | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | catalogued as rs1057517667, CM155938, COSV51550682, COSV99292078; ClinVar: pathogenic; called by muse, mutect2
- ABCA4 | c.4930C>A p.P1644T | Missense Mutation (SNP) | VAF 25/729 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100933157; called by muse, mutect2
- ABCA5 | c.2980C>A p.H994N | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.057); catalogued as rs1567758545, COSV67017461; called by muse, mutect2, varscan2
- ABCC5 | c.1685A>G p.E562G | Missense Mutation (SNP) | VAF 90/1264 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99657083; called by muse, mutect2
- ABL2 | c.770C>A p.T257K (on ENST00000502732 / NM_007314.4; = p.T242K on NM_005158.5) | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100772833; called by muse, mutect2
- ADCY10 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV100896924; called by muse, mutect2
- ADK | c.194+2T>G p.X65_splice (on ENST00000286621; = p.X48_splice on NM_001123.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 44/238 reads (18%) | catalogued as COSV54209627; called by muse, mutect2, varscan2
- AFF1 | c.2705G>A p.S902N | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.598); catalogued as rs752168608, COSV100320772; called by muse, mutect2
- AKIRIN2 | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100005245; called by muse, mutect2, varscan2
- ALG13 | c.3333T>G p.I1111M | Missense Mutation (SNP) | VAF 159/557 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV99322495; called by muse, mutect2, varscan2
- AMHR2 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 50/1475 reads (3%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.651); catalogued as COSV99143306; called by muse, mutect2
- ARAP1 | c.1213+2T>C p.X405_splice (on ENST00000393609 / NM_001040118.2; = p.X160_splice on NM_015242.4) | Splice Site (SNP) | VAF 528/694 reads (76%) | catalogued as rs1434429907, COSV100501988; called by muse, mutect2, varscan2
- ARFGEF1 | c.3913G>A p.V1305I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as COSV51611127; called by muse, varscan2
- ARG1 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 149/801 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as CD137584, COSV51581260; called by muse, mutect2, varscan2
- ARHGAP22 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50941859; called by muse, mutect2, varscan2
- ARIH1 | c.681+1G>A p.X227_splice | Splice Site (SNP) | VAF 12/76 reads (16%) | catalogued as COSV65912033; called by muse, mutect2
- ASH1L | c.3680T>C p.F1227S | Missense Mutation (SNP) | VAF 245/1323 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as rs1167288754, COSV64209522; called by muse, mutect2, varscan2
- ASIC4 | c.1563G>T p.*521Yext*108 (on ENST00000347842 / NM_182847.3; = p.*540Yext*108 on NM_018674.6) | Nonstop Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as CM164010, COSV61732313; called by muse, mutect2, varscan2
- BAZ2A | c.2965A>C p.I989L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV99466679; called by muse, varscan2
- BEST2 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 64/338 reads (19%) | catalogued as rs1568352894, COSV50368120; called by muse, mutect2, varscan2
- BMPR1A | c.1115A>T p.K372I | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100923609; called by muse, mutect2
- CAPN10 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54377381; called by muse, mutect2, varscan2
- CAPN11 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 86/408 reads (21%) | catalogued as COSV67238108; called by muse, mutect2, varscan2
- CD38 | c.356G>C p.C119S | Missense Mutation (SNP) | VAF 138/420 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56891189; called by muse, mutect2, varscan2
- CDK17 | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 204/1423 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1343777100, COSV54130716; called by muse, mutect2, varscan2
- CENPJ | c.367A>T p.N123Y | Missense Mutation (SNP) | VAF 93/553 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV67883642; called by muse, mutect2, varscan2
- CENPP | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.054); catalogued as COSV65039449; called by muse, mutect2, varscan2
- CHD1L | c.1684A>T p.S562C | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV63614467; called by muse, mutect2, varscan2
- CNTNAP1 | c.1508T>C p.F503S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52851706; called by muse, mutect2
- COL5A3 | c.2521A>T p.R841W | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99319121; called by muse, mutect2, varscan2
- CTNNAL1 | c.1159A>C p.S387R | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.327); catalogued as COSV57703846; called by muse, mutect2, varscan2
- CYP7A1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 210/1172 reads (18%) | catalogued as COSV100052447; called by muse, varscan2
- DDX17 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 212/568 reads (37%) | catalogued as COSV99318094; called by muse, mutect2, varscan2
- DDX4 | c.32A>C p.N11T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV61755674; called by muse, mutect2, varscan2
- DENND2C | c.1797C>G p.C599W (on ENST00000393274 / NM_001256404.2; = p.C542W on NM_198459.4) | Missense Mutation (SNP) | VAF 24/718 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101283946; called by muse, mutect2
- DENND5B | c.2982G>C p.Q994H | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100171666; called by muse, mutect2
- DHX34 | c.447T>G p.F149L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV60896007; called by muse, mutect2, varscan2
- DLG1 | c.1391C>G p.P464R | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772348654, COSV58385452; called by muse, mutect2, varscan2
- DLST | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 44/1240 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99472025; called by muse, mutect2
- DNAJC7 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 154/597 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs200650446, COSV57269407; called by muse, mutect2, varscan2
- DNMT1 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 30/555 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100532628; called by muse, mutect2
- DOP1A | c.4003T>C p.Y1335H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52712418; called by muse, mutect2, varscan2
- DST | c.13426G>C p.A4476P (on ENST00000361203 / NM_001374722.1; = p.A2064P on NM_015548.5) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99757554; called by muse, mutect2
- EIF2D | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as COSV55114207; called by muse, mutect2, varscan2
- EMILIN1 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs1226693512, COSV53155437; called by muse, mutect2
- EOGT | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55152032; called by muse, mutect2, varscan2
- EPB41 | c.2111G>C p.W704S (on ENST00000343067 / NM_001166005.2; = p.W462S on NM_004437.4) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58049133; called by muse, mutect2, varscan2
- EPC1 | c.2195A>C p.H732P | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.856); catalogued as COSV53927139; called by muse, mutect2, varscan2
- ERICH6 | c.1870A>T p.K624* | Nonsense Mutation (SNP) | VAF 77/376 reads (20%) | catalogued as COSV55801404; called by muse, mutect2, varscan2
- EVI2B | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 151/1023 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs906194437, COSV58364328, COSV58364857; called by muse, mutect2, varscan2
- FAM222B | c.1354C>G p.P452A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV57931752; called by muse, mutect2, varscan2
- FBN1 | c.938G>C p.C313S | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57320803; called by muse, mutect2, varscan2
- FLG | c.7318G>A p.G2440R | Missense Mutation (SNP) | VAF 32/796 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV64238500; called by muse, mutect2
- FNDC1 | c.2489G>T p.R830M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV51940770; called by muse, mutect2, varscan2
- FNIP1 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV57197579; called by muse, mutect2
- FRK | c.435T>A p.S145R | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV73384044; called by muse, mutect2, varscan2
- GALNT12 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66662226, COSV66662969; called by muse, mutect2, varscan2
- GALR1 | c.866A>G p.H289R | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55315750; called by muse, mutect2, varscan2
- GATA3 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1465086730, COSV60519947, COSV60520577; called by muse, mutect2, varscan2
- GNAS | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 114/1096 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV55679561; called by muse, mutect2, varscan2
- H1-1 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 120/560 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.283); catalogued as COSV55119793; called by muse, mutect2, varscan2
- HDX | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV52978331; called by muse, mutect2, varscan2
- HECW2 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53650571, COSV53663626; called by muse, mutect2, varscan2
- HGS | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100230586; called by muse, mutect2, varscan2
- HOXB6 | c.533A>T p.E178V | Missense Mutation (SNP) | VAF 82/1518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99494592; called by muse, mutect2
- HOXC6 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 327/1194 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as COSV54536949, COSV54537327; called by muse, mutect2, varscan2
- IGSF10 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 227/901 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372867906; called by muse, mutect2, varscan2
- INVS | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52444774, COSV52448143, COSV99317700; called by muse, mutect2, varscan2
- INVS | c.1772A>T p.D591V | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99317702; called by muse, mutect2, varscan2
- KDM5B | c.4628G>A p.R1543Q | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.389); catalogued as rs761912360, COSV99350367; called by muse, mutect2
- KIAA1755 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 60/504 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as rs561742884, COSV54077738; called by muse, mutect2, varscan2
- KNG1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 140/1266 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs199853757; called by muse, mutect2, varscan2
- KRT24 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52880276, COSV99232062; called by muse, mutect2
- KRT28 | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60685511; called by muse, mutect2, varscan2
- KRTAP5-9 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 15/362 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV101603638, COSV73200230; called by muse, mutect2
- LGR6 | c.1607A>G p.D536G (on ENST00000367278 / NM_001017403.1; = p.D484G on NM_021636.3) | Missense Mutation (SNP) | VAF 287/1119 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV55159723; called by muse, mutect2, varscan2
- LIMK2 | c.975C>G p.I325M | Missense Mutation (SNP) | VAF 181/393 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59183031; called by muse, mutect2, varscan2
- LRRK2 | c.5268C>A p.D1756E | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1394072553, COSV54157913; called by muse, mutect2, varscan2
- LSAMP | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.099); catalogued as COSV99048800; called by muse, mutect2
- LSMEM2 | c.450C>G p.S150R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV57114257; called by muse, mutect2, varscan2
- LYAR | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 347/735 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as rs752653540, COSV58642168, COSV58643610; called by muse, mutect2, varscan2
- MAGI3 | c.2210G>C p.G737A | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56838533; called by muse, varscan2
- MAP3K19 | c.3543T>A p.C1181* | Nonsense Mutation (SNP) | VAF 71/508 reads (14%) | catalogued as COSV59639926; called by muse, mutect2, varscan2
- MDGA2 | c.2686C>A p.P896T (on ENST00000399232 / NM_001113498.2; = p.P598T on NM_182830.4) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV62098938; called by muse, mutect2, varscan2
- MED23 | c.1702A>C p.S568R | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100645133; called by muse, mutect2, varscan2
- MGAT2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV100023576; called by muse, mutect2
- MRTFA | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 373/1106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62934223; called by muse, mutect2, varscan2
- MTMR12 | c.902A>T p.Y301F | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.321); catalogued as rs1183370670, COSV99373733; called by muse, mutect2, varscan2
- MYO5C | c.3351A>C p.E1117D | Missense Mutation (SNP) | VAF 64/676 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55908122; called by muse, mutect2
- MYOM1 | c.2858G>A p.G953E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV55294281; called by muse, mutect2, varscan2
- NAV3 | c.4078A>T p.T1360S | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.99); catalogued as COSV57089399; called by muse, mutect2, varscan2
- NCBP1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100912627; called by muse, mutect2, varscan2
- NCKAP1 | c.3302A>G p.D1101G | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62941756; called by muse, varscan2
- NKAIN1 | c.614+1G>C p.X205_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as rs1340877998, COSV55274898; called by muse, mutect2, varscan2
- NLRC5 | c.4975G>T p.V1659F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV52657677; called by muse, mutect2, varscan2
- NPHP4 | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs896120232, COSV65395735; called by mutect2, varscan2
- NR1H3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 98/367 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160546592, COSV68008531; called by muse, varscan2
- NT5DC3 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV101230994; called by muse, mutect2
- OOSP2 | c.442T>A p.L148I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); catalogued as COSV53929282; called by muse, mutect2, varscan2
- OR1K1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs552980669, COSV52956726; called by muse, mutect2, varscan2
- OR8D1 | c.579C>G p.H193Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100766524, COSV63442565; called by muse, mutect2
- PARP10 | c.1289T>G p.V430G | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV57298409; called by muse, mutect2, varscan2
- PCSK9 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100135500, COSV56160654; called by muse, mutect2, varscan2
- PHC1 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.543); catalogued as rs757415794, COSV70418201; called by muse, mutect2, varscan2
- PIWIL3 | c.2575C>G p.L859V | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59996311; called by muse, mutect2, varscan2
- PKHD1L1 | c.12206G>C p.R4069T | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV65745985; called by muse, mutect2
- PRDM12 | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53390899; called by muse, mutect2, varscan2
- PTCD1 | c.1740G>A p.K580= | Splice Region (SNP) | VAF 238/768 reads (31%) | catalogued as COSV52864675; called by muse, mutect2, varscan2
- PTCH1 | c.3301G>T p.A1101S | Missense Mutation (SNP) | VAF 52/422 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV59480233; called by muse, varscan2
- PTCRA | c.155T>A p.V52D | Missense Mutation (SNP) | VAF 169/741 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV58975985; called by muse, mutect2, varscan2
- PTPRG | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55647225; called by muse, mutect2, varscan2
- RMI1 | c.1122T>A p.S374R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100366339; called by muse, mutect2, varscan2
- RMI1 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100366342, COSV57936763; called by muse, mutect2, varscan2
- RNF19B | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99331536; called by muse, mutect2, varscan2
- RTL9 | c.3772C>A p.L1258M | Missense Mutation (SNP) | VAF 60/522 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101511721; called by muse, varscan2
- S1PR5 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV61014074; called by muse, mutect2, varscan2
- SAMSN1 | c.609G>T p.W203C | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53477905, COSV99581716; called by muse, mutect2
- SBNO1 | c.3251T>C p.L1084P (on ENST00000420886; = p.L1083P on NM_018183.5) | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57342863; called by muse, mutect2, varscan2
- SI | c.2566A>G p.N856D | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100016049; called by muse, varscan2
- SLC25A21 | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 29/696 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as COSV100491531; called by muse, mutect2
- SLC25A44 | c.792G>C p.Q264H | Missense Mutation (SNP) | VAF 100/769 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs977233917, COSV60771811; called by muse, mutect2, varscan2
- SLC35F3 | c.637C>A p.L213I (on ENST00000366617 / NM_001300845.1; = p.L282I on NM_173508.4) | Missense Mutation (SNP) | VAF 524/2420 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV64020335; called by muse, varscan2
- SLC5A7 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs763020957, COSV50890306; called by muse, mutect2, varscan2
- SLITRK2 | c.1536A>C p.K512N | Missense Mutation (SNP) | VAF 85/114 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV59426569; called by muse, mutect2, varscan2
- SORCS3 | c.795+2T>C p.X265_splice | Splice Site (SNP) | VAF 102/455 reads (22%) | catalogued as COSV63814333; called by muse, mutect2, varscan2
- SPATA16 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 127/255 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV63530440; called by muse, mutect2, varscan2
- SPEG | c.6618dup p.A2207Rfs*116 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | catalogued as rs759644676; called by pindel, varscan2
- ST8SIA5 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 221/913 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV59332961; called by muse, mutect2, varscan2
- STAP1 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99609519; called by muse, mutect2
- STK24 | c.965C>G p.A322G | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64823179; called by muse, mutect2, varscan2
- STPG2 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54786871; called by muse, mutect2
- SUMF1 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 33/386 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV55992621, COSV99794872; called by muse, mutect2
- SYNE2 | c.10906G>C p.E3636Q | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV59955616; called by muse, mutect2, varscan2
- TAAR6 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs753471109, COSV51584046; called by muse, mutect2, varscan2
- TGFB1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 34/849 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs774002594, COSV99700217; called by muse, mutect2
- THBS1 | c.2638G>C p.A880P | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99528069; called by mutect2, varscan2
- THEMIS | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768345674, COSV64071934; called by muse, mutect2, varscan2
- TNRC18 | c.4091G>C p.G1364A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV68166574; called by muse, mutect2, varscan2
- TPO | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV61104341; called by muse, mutect2
- TTN | c.101705A>T p.K33902I (on ENST00000591111; = p.K26478I on NM_003319.4) | Missense Mutation (SNP) | VAF 25/678 reads (4%) | PolyPhen benign (0.055); catalogued as COSV100618439; called by muse, mutect2
- TTN | c.76694T>C p.I25565T (on ENST00000591111; = p.I18141T on NM_003319.4) | Missense Mutation (SNP) | VAF 96/378 reads (25%) | PolyPhen benign (0.003); catalogued as rs369868913, COSV60411645; called by muse, mutect2, varscan2
- TTN | c.64404G>T p.E21468D (on ENST00000591111; = p.E14044D on NM_003319.4) | Missense Mutation (SNP) | VAF 72/1046 reads (7%) | PolyPhen benign (0.026); catalogued as COSV100618445; called by muse, mutect2
- TTN | c.36601G>T p.A12201S (on ENST00000591111; = p.A4777S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/556 reads (4%) | PolyPhen benign (0.003); catalogued as COSV100618448, COSV59920967; called by muse, mutect2
- UBE2K | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99787273; called by muse, mutect2
- VCPIP1 | c.1438G>C p.V480L | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as COSV60048598; called by muse, mutect2, varscan2
- ZC2HC1A | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.033); catalogued as COSV55669552; called by muse, mutect2, varscan2
- ZFX | c.1892A>G p.K631R | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100457801; called by muse, mutect2
- ZKSCAN5 | c.1011G>C p.K337N | Missense Mutation (SNP) | VAF 278/1897 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV58743259; called by muse, mutect2, varscan2
- ZNF107 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100788414; called by muse, mutect2, varscan2
- ZNF14 | c.190A>C p.R64= | Splice Region (SNP) | VAF 102/513 reads (20%) | catalogued as COSV59850099; called by mutect2, varscan2
- ZNF232 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV51503886; called by muse, mutect2, varscan2
- ZNF519 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.028); catalogued as COSV73913330; called by muse, mutect2
- ZNF710 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV51563867; called by muse, mutect2, varscan2
- CDK3 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- FAM53B | c.-11_36del | Translation Start Site (DEL) | VAF 81/868 reads (9%) | called by mutect2, pindel
- LGI3 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.432); called by mutect2, varscan2
- LRRC47 | c.782_817del p.G261_A272del | In Frame Del (DEL) | VAF 8/110 reads (7%) | called by mutect2, pindel
- MPV17L2 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROCK1 | c.2655-21_2661del p.X885_splice | Splice Site (DEL) | VAF 99/511 reads (19%) | called by mutect2, pindel
- RORA | c.1513C>G p.P505A (on ENST00000335670 / NM_134261.3; = p.P530A on NM_002943.3) | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.8); called by mutect2, varscan2
- SP140 | c.1546del p.E516Kfs*24 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- SPTBN2 | c.6568del p.A2190Pfs*127 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- AARS1 | c.2886C>G p.R962= | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as COSV55748062; called by muse, mutect2, varscan2
- ABCC9 | c.2475G>A p.A825= | Silent (SNP) | VAF 272/1037 reads (26%) | catalogued as rs587780845, COSV53976047; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- ACTRT3 | c.777C>T p.F259= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100377507, COSV57754382; called by muse, mutect2
- ACVR1B | c.1008A>G p.L336= | Silent (SNP) | VAF 30/402 reads (7%) | catalogued as COSV99231574; called by muse, mutect2
- ADH7 | c.909T>G p.V303= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV99265321; called by muse, varscan2
- AFF1 | c.1326G>A p.E442= | Silent (SNP) | VAF 22/462 reads (5%) | catalogued as COSV100320769; called by muse, mutect2
- AHNAK | c.12132T>C p.I4044= | Silent (SNP) | VAF 21/736 reads (3%) | catalogued as rs1488317557, COSV99948096; called by muse, mutect2
- AHNAK2 | c.11697C>G p.V3899= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs556940298, COSV100317969, COSV100318673, COSV60933304; called by muse, mutect2
- CCNDBP1 | c.150G>A p.E50= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV53041629; called by muse, mutect2
- CLCN1 | c.354G>C p.G118= | Silent (SNP) | VAF 41/1083 reads (4%) | catalogued as COSV100578172; called by muse, mutect2
- CLDND1 | c.594C>G p.L198= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV57859108; called by muse, mutect2
- DAP3 | c.645C>T p.S215= | Silent (SNP) | VAF 25/261 reads (10%) | catalogued as rs750306311, COSV58021385; called by muse, mutect2, varscan2
- ELK3 | c.336C>T p.C112= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs1231935719, COSV57387203; called by muse, mutect2, varscan2
- ERCC4 | c.2094G>A p.L698= | Silent (SNP) | VAF 31/1010 reads (3%) | catalogued as COSV100318947; called by muse, mutect2
- ESYT1 | c.2013G>A p.K671= | Silent (SNP) | VAF 396/769 reads (51%) | catalogued as COSV57274292; called by muse, varscan2
- FARP2 | c.1732C>T p.L578= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV50873344; called by muse, mutect2, varscan2
- FLNA | c.6573G>T p.V2191= (on ENST00000369850 / NM_001110556.2; = p.V2183= on NM_001456.3) | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as COSV100774854; called by muse, mutect2, varscan2
- FOXRED2 | c.939C>T p.A313= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs764922316, COSV99340996; called by muse, mutect2, varscan2
- GALNT2 | c.240C>T p.D80= | Silent (SNP) | VAF 183/694 reads (26%) | catalogued as COSV64195799; called by muse, mutect2, varscan2
- GPR27 | c.876C>T p.L292= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55205357; called by muse, mutect2, varscan2
- H1-4 | c.651G>A p.K217= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs139391118, COSV56801628, COSV56802992; called by muse, mutect2
- KCNMB1 | c.90C>G p.T30= | Silent (SNP) | VAF 150/308 reads (49%) | catalogued as rs112318935, COSV51132161, COSV51133056; called by muse, mutect2, varscan2
- KPNB1 | c.2550G>T p.G850= | Silent (SNP) | VAF 142/598 reads (24%) | catalogued as COSV99268206; called by muse, mutect2, varscan2
- MALT1 | c.1077C>T p.L359= | Silent (SNP) | VAF 54/259 reads (21%) | catalogued as COSV61935365; called by muse, mutect2, varscan2
- MARK1 | c.1209C>G p.S403= | Silent (SNP) | VAF 96/400 reads (24%) | catalogued as COSV65068539; called by muse, mutect2, varscan2
- MGAT5 | c.741C>T p.D247= | Silent (SNP) | VAF 19/257 reads (7%) | catalogued as rs751746374, COSV56097262; called by muse, mutect2
- MUC17 | c.6546A>T p.S2182= | Silent (SNP) | VAF 91/593 reads (15%) | catalogued as COSV60281690, COSV60292766; called by muse, mutect2, varscan2
- NEB | c.8337C>A p.I2779= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV51428482; called by muse, mutect2, varscan2
- NOMO1 | c.1296C>T p.V432= | Silent (SNP) | VAF 32/102 reads (31%) | called by mutect2, varscan2
- PLCB4 | c.3042A>G p.K1014= | Silent (SNP) | VAF 68/329 reads (21%) | catalogued as COSV53806042; called by muse, mutect2, varscan2
- PROSER1 | c.444C>G p.P148= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV61488245; called by muse, mutect2, varscan2
- SCIMP | c.366A>C p.P122= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as COSV68311092; called by muse, mutect2, varscan2
- SH3TC2 | c.3651C>A p.G1217= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as COSV100101915; called by muse, mutect2
- SHBG | c.1068C>T p.D356= | Silent (SNP) | VAF 58/736 reads (8%) | catalogued as COSV100503105; called by muse, mutect2
- SRCAP | c.2970C>G p.V990= | Silent (SNP) | VAF 130/1061 reads (12%) | catalogued as rs770723052, COSV52675286; called by muse, mutect2, varscan2
- SRPK2 | c.438C>T p.V146= | Silent (SNP) | VAF 89/865 reads (10%) | catalogued as COSV61962061; called by muse, mutect2, varscan2
- TMEM171 | c.456C>T p.D152= | Silent (SNP) | VAF 87/383 reads (23%) | catalogued as COSV99825014; called by muse, mutect2, varscan2
- TRIM47 | c.1131C>T p.C377= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1039865400, COSV54668712; called by muse, mutect2
- TSPAN16 | c.141C>T p.L47= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as rs771486767, COSV57442658; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1983G>C p.L661= | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as COSV51956996; called by muse, mutect2, varscan2
- UST | c.483A>G p.Q161= | Silent (SNP) | VAF 25/272 reads (9%) | catalogued as rs1178083219, COSV100820054; called by muse, mutect2
- WWC3 | c.1209C>G p.P403= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV66504364; called by muse, mutect2, varscan2
- AP001042.1 | n.2212T>A | RNA (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.84+66C>G | Intron (SNP) | VAF 298/1626 reads (18%) | catalogued as COSV99180714; called by muse, mutect2, varscan2
- C5orf24 | c.*2T>C | 3'UTR (SNP) | VAF 46/132 reads (35%) | catalogued as COSV100574535; called by muse, mutect2, varscan2
- C9orf106 | n.563C>T | RNA (SNP) | VAF 11/44 reads (25%) | catalogued as rs1490915027; called by muse, mutect2, varscan2
- TNS2 | chr12:53049147 G>A | 5'Flank (SNP) | VAF 24/296 reads (8%) | catalogued as COSV100048360; called by muse, mutect2
- ZNF467 | chr7:149778014 G>A | 5'Flank (SNP) | VAF 13/47 reads (28%) | catalogued as rs182533871, COSV50488049; called by muse, mutect2, varscan2
